Gene-level copy-number profile of tumor specimen TCGA-CZ-5469-01A from TCGA case TCGA-CZ-5469, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 41.7 years (15,242 days).
Specimen TCGA-CZ-5469-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRC.e4999a00-44bc-45ca-b6b7-6025ce63de8b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CZ-5469-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2da722f5-6c1e-4819-a794-394a23b8787a

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 13; copy number 3: 6,910; copy number 4: 22,708; copy number 5: 7,258; copy number 6: 14,232; copy number 7: 3,376; copy number 8: 4,185; copy number 9: 1,094; copy number 12: 40.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CZ-5469-01A-01D-1499-01): tumor purity 0.68, ploidy 4.99, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,134 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:135,965,728–198,222,513, 1,086 genes, copy number 9 (broad region; genes not listed).
- chr4:157,768,013–160,586,817, 40 genes, copy number 12: Y_RNA, AC017037.1, AC017037.3, AC017037.5, AC084740.1, AC017037.4, AC017037.2, AC098679.2, AC098679.3, GASK1B, FAM198B-AS1, AC098679.5, NUDT19P5, AC098679.1, TMEM144, AC098679.4, AIDAP2, RXFP1, RNU4-79P, AC121161.1, AC121161.2, C4orf46, ETFDH, U3, PPID, FNIP2, RNU6-128P, C4orf45, SNORD39, PSME2P3, FABP5P12, Y_RNA, RAPGEF2, MIR3688-1, MIR3688-2, AC074344.1, AC074344.2, LINC02233, AC093853.1, LINC02477.
- chr5:130,989,897–131,398,447, 7 genes, copy number 9: AC113367.1, AC113367.3, AC113367.2, HINT1, LYRM7, CDC42SE2, AC004777.1.
- chr5:131,440,031–131,440,196, 1 gene, copy number 9: AC008497.1.

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
